Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A4PQ, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A4PQ-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

ICD 0-3

*Malignant Mullerian Mixed Tumor
8950/3*

*Site: Endometrium, C54.1
12/14/12 QJD*

Diagnosis:

A: Uterus, cervix and right adnexa, hysterectomy and right salpingo-oophorectomy:

Location of tumor: Predominantly posterior endometrium.

Histologic type: Malignant mixed m llerian tumor with heterologous elements (serous carcinoma and malignant cartilaginous and rhabdomyosarcomatous differentiation) [See comment].

Histologic grade (FIGO): Grade 3

Extent of invasion: Minimal myometrial invasion, extensive lymphovascular space invasion and lymph node involvement.

Myometrial invasion: Inner half (A10 and A11)

Depth: 2mm Wall thickness: 25mm Percent: 8%

Serosal involvement: Absent.

Lower uterine segment involvement: Present as lymphovascular space invasion only.

Cervical involvement: Present as lymphovascular space invasion only.

Adnexal involvement: Present as lymphovascular space invasion surrounding right fallopian tube.

Cervical/vaginal margin and distance: Widely negative.

Lymphovascular space invasion: Present and extensive.

Regional lymph nodes (see parts B-D):

Total number involved: 13

Total number examined: 18

Other pathologic findings:

- Cervix: Otherwise unremarkable
- Endometrium: Endometrial intraepithelial carcinoma.
- Myometrium: Multiple leiomyomata (measuring up to 4.0 cm)
- Left fallopian tube remnant: Changes consistent with prior

[page 2 of 5]
tubal ligation and peritubal cyst.

- Right ovary: Age related changes and benign inclusion cysts
- Right fallopian tube: Changes consistent with prior tubal ligation.

AJCC Pathologic Stage: pT1a pN2 pMx

FIGO (2008 classification) Stage grouping: IIIC2

B: Lymph nodes, left pelvic, regional dissection:

- Three of eight lymph nodes positive for metastatic malignancy (3/8).

C: Lymph nodes, right pelvic, regional dissection:

- Four of four lymph nodes positive for metastatic malignancy (4/4).

D: Lymph nodes, right peri-aortic, regional dissection:

- Six of six lymph nodes positive for metastatic malignancy (6/6).

Comment:

An immunohistochemical stain for myogenin was performed on block A13 with appropriate controls; the myogenin is focally positive, which is supportive of the above diagnosis.

Clinical History:

-year-old female with endometrial cancer.

Gross Description:

Received are four formalin-filled containers.

Container A is additionally labeled "uterus and cervix, right ovary and tube."

Adnexa: right tube and ovary present and attached; left fallopian tube remnant attached

Weight: 135.0 grams

Shape: pear shaped

Dimensions:

height: 8.3 cm

anterior to posterior width: 6.4 cm

breadth at fundus: 4.7 cm

[page 3 of 5]
Serosa: tan/brown, smooth and glistening with adhesions on the posterior surface

Cervix:

ectocervix: tan/white, smooth

endocervix: tan/yellow, trabecular

length of endocervical canal: 2.4 cm

Endomyometrium:

length of endometrial cavity: 2.7 cm

width of endometrial cavity at fundus: 2.0 cm

tumor findings:

dimensions: 4.5 x 4.1 x 3.7 cm

appearance: tan/brown, soft, polypoid, multinodular

location and extent: The majority is located in posterior endometrial cavity, present in anterior endometrial cavity, grossly does not appear to extend to lower uterine segment.

myometrial invasion: outer one-half

thickness of myometrial wall at deepest gross invasion: 2.3 cm

other findings or comments: In the anterior myometrium there is a 4.0 x 3.4 x 1.9 cm well circumscribed white/pink soft intramural nodule. This nodule encompasses almost the entire myometrium and is reminiscent of a classic fibroid.

Adnexa:

Right ovary:

dimensions: 2.1 x 1.8 x 1.1 cm

external surface: tan/yellow, smooth with adhesions

cut surface: grossly unremarkable

Right fallopian tube:

dimensions: 3.8 cm in length, 0.4 cm in diameter

other findings: The tube is received discontinuance, proximal portion of right fallopian tube has a patent lumen. The distal portion of the right fallopian tube is brown/gray with a pinpoint lumen. Also, there is one focal area of possible fallopian tube with multiple paratubal cysts about 0.1 cm to 0.3 cm in range.

Left ovary: absent

Left fallopian tube:

dimensions: 1.1 cm in length, 0.4 cm in diameter

other findings: patent lumen, paratubal cyst measuring 1.0 x 0.8 x 0.7 cm filled with dark yellow mucinous material; fimbria is absent

Lymph nodes: none submitted

Other comments: anterior parametrium is inked in blue for orientation

Digital photograph taken: no

Tissue submitted for special investigations: yes; tumor is submitted to the tumor procurement foundation

[page 4 of 5]
Block Summary:

A1 - anterior cervix
A2 - anterior lower uterine segment
A3,A4 - mid corpus, full thickness, bisected
A5,A6 - anterior upper corpus, full thickness, bisected
A7 - posterior cervix
A8 - posterior lower uterine segment
A9 - posterior mid corpus, full thickness
A10,A11 - posterior upper corpus, full thickness, bisected
A12-A14 - additional sections of tumor
A15 - left fallopian tube remnant and paratubal cyst
A16 - right ovary and right proximal fallopian tube, transverse section
A17 - right fallopian tube, distal portion
A18 - longitudinal section of right fallopian tube tip and fimbria
Tissue remains in formalin.

Container B is additionally labeled "left pelvic lymph nodes."
It consists of a 5.0 x 4.0 x 1.2 cm aggregate of fatty tissue fragments. The tissue is dissected for lymph node candidates. Seven lymph node candidates were identified ranging from 0.3 to 3.6 x 2.1 x 0.6 cm in greatest dimension.

Block Summary:

B1-B6 - one lymph node candidate, serially sectioned
B7 - one lymph node candidate, serially sectioned
B8,B9 - one lymph node candidate, serially sectioned
B10 - multiple lymph node candidates
B11-B13 - remainder of specimen with potential lymph node candidates,

Container C is additionally labeled "right pelvic lymph nodes."
It consists of a 4.0 x 4.0 x 1.2 cm aggregate of fatty tissue fragments. The specimen is dissected for lymph node candidates. Four lymph nodes are identified ranging in size from 0.5 to 1.2 x 0.6 x 0.5 cm in greatest dimension.

Block summary:

C1-C4 - one lymph node candidate, each, serially sectioned
C5-C9 - remainder of specimen with potential lymph node candidates,

Container D is additionally labeled "right periaortic lymph

[page 5 of 5]
nodes." It consists of a 2.3 x 1.4 x 0.5 cm fatty tissue fragment. The specimen was dissected for lymph node candidates. Three lymph node candidates are identified ranging from 0.2 to 1.5 x 0.6 x 0.3 cm in greatest dimension.

Block summary:

- D1 - one lymph node candidate, serially sectioned
- D2 - one lymph node candidate, serially sectioned
- D3 - one lymph node candidate, bisected
- D4 - remaining tissue for possible lymph node candidates,

	Yes	No
Preparation		X
Staining		X
Mounting		X
Quality of slides		X

Lmt

Source: NCI Genomic Data Commons file 7a16ded2-05c9-4e4e-85bf-d3254a763f6c (TCGA-N8-A4PQ.31816D42-F2BA-4A85-86B9-0DEA359F7EAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).